Somatic mutation profile of tumor specimen TCGA-2G-AAHG-01A (aliquot TCGA-2G-AAHG-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAHG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 25.9 years (9,476 days).
Specimen TCGA-2G-AAHG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29b4cc15-abfc-4d8e-bc7c-c47b813040fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHG-10A (Blood Derived Normal), aliquot TCGA-2G-AAHG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4425d8d6-2ade-49cd-8840-15f073228eaa

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD10 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as rs150236189; called by muse, mutect2, varscan2
- FGF20 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51662445; called by muse, mutect2, varscan2
- ISM2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV53633878; called by muse, mutect2
- WBP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/135 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs751609652; called by muse, mutect2, varscan2
- ACACA | c.6985A>C p.I2329L | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DMAC2L | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SINHCAF | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF433 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RPLP0 | c.205C>T p.L69= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs982025813; called by muse, mutect2, varscan2
- TAOK2 | c.3195G>A p.A1065= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs745789449; called by muse, mutect2, varscan2
- VCX3B | c.657G>A p.Q219= | Silent (SNP) | VAF 168/408 reads (41%) | catalogued as rs774245556, COSV66842413; called by muse, mutect2, varscan2
- AC116366.2 | c.-637-10380C>T | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as rs992055378; called by muse, mutect2, varscan2
